Gene-level copy-number profile of tumor specimen HTMCP-03-06-02037-01B from CGCI case HTMCP-03-06-02037, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G3.
Specimen HTMCP-03-06-02037-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dbea69b6-996e-433e-800f-7cf07f3c702e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02037-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/f545fbf8-627b-4d8a-9550-d4b67468a315

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 4,351; copy number 2: 46,635; copy number 3: 4,281; copy number 4: 2,046; copy number 5: 612; copy number 6: 467; copy number 7: 4.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,588,772–49,589,529, 1 gene: SNX18P25.
- chr13:52,488,993–52,587,095, 2 genes: AL137058.1, AL137058.3.
- chr13:57,314,739–57,315,909, 1 gene: SLC25A5P4.
- chr19:1,203,209–1,203,842, 1 gene (within-gene range 0–1): HMGB2P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,083 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:172,425,850–198,123,232, 508 genes, copy number 5–6 (broad region; genes not listed).
- chr6:157,289,025–157,324,477, 3 genes, copy number 7: TMEM242, LDHAL6FP, AL390955.2.
- chr14:22,040,594–22,505,167, 66 genes, copy number 5 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr19:27,638,483–40,465,764, 477 genes, copy number 5 (broad region; genes not listed).
- chr21:8,603,547–8,603,984, 1 gene, copy number 7: RPSAP68.
- chr22:49,414,524–50,085,426, 27 genes, copy number 5: C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, AL023802.1, RN7SKP252, RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821, IL17REL, TTLL8, MLC1.

Autosomal genes at a single copy (total copy number 1): 4,351. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
